Somatic mutation profile of tumor specimen TCGA-IR-A3LK-01A (aliquot TCGA-IR-A3LK-01A-12D-A20U-09) from TCGA case TCGA-IR-A3LK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 69.7 years (25,440 days).
Specimen TCGA-IR-A3LK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c04b2829-83dc-447d-baf6-ff616dce7651.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IR-A3LK-10A (Blood Derived Normal), aliquot TCGA-IR-A3LK-10A-01D-A20U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3faeb1a-02a9-47fa-95be-0a315e03d8d4

The open-access MAF lists 1,455 somatic variants for this specimen: 1,076 protein-altering or splice-affecting, 345 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 944, Silent 345, Nonsense Mutation 95, Intron 17, Splice Site 15, Splice Region 7, RNA 6, Nonstop Mutation 5, Frame Shift Ins 5, 3'Flank 4, 5'UTR 3, 5'Flank 3.

Variants (750 of 1,455; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLF5 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66613960, COSV66613967; called by muse, mutect2
- NF1 | c.1627C>T p.Q543* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as rs894292181, CM020463, COSV62211373; ClinVar: pathogenic; called by muse, varscan2
- OTOF | c.4030C>T p.R1344* (on ENST00000272371 / NM_194248.3; = p.R577* on NM_004802.4) | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as rs1060499805, CM102203, COSV55511670; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PRNP | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs74315410, CM014372, COSV65173942; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAAS | c.824C>G p.S275* | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as COSV52933766; called by muse, mutect2, varscan2
- AASDH | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); catalogued as rs757073822, COSV52708718; called by muse, mutect2, varscan2
- ABCB7 | c.657G>C p.Q219H (on ENST00000373394 / NM_001271696.3; = p.Q220H on NM_004299.6) | Missense Mutation (SNP) | VAF 96/141 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as COSV53722090, COSV99504998; called by muse, mutect2, varscan2
- ABCC2 | c.4612G>A p.E1538K | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.08); catalogued as COSV64987541; called by muse, mutect2, varscan2
- ABCC6 | c.4279G>A p.E1427K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756910757, CM091245, COSV52743066; called by muse, mutect2, varscan2
- ABCC8 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1405170371, COSV56854714; called by muse, mutect2, varscan2
- ABCD1 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557052367, CM016228, CM950032, COSV54386784; called by muse, mutect2, varscan2
- ABCG1 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1321363363, COSV59208095; called by muse, mutect2, varscan2
- AC068580.4 | c.320C>G p.S107C | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52589354; called by muse, mutect2, varscan2
- AC244197.3 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.036); catalogued as COSV61713491; called by muse, mutect2, varscan2
- ACACB | c.1433G>C p.R478T | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58141261; called by muse, mutect2, varscan2
- ACADS | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as rs756016434, COSV54368224; called by muse, mutect2, varscan2
- ACAN | c.6608C>G p.S2203C | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61365587; called by muse, varscan2
- ACOT2 | c.620G>C p.R207P | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs775410758, COSV53151055; called by muse, mutect2, varscan2
- ACTG1 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV59511347; called by muse, mutect2, varscan2
- ACTL6A | c.1289G>C p.*430Sext*54 | Nonstop Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV52023605; called by muse, mutect2, varscan2
- ACTN4 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV53148534; called by muse, mutect2, varscan2
- ACTR1A | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV64023915; called by muse, mutect2, varscan2
- ADAM28 | c.1462G>C p.D488H | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56103179, COSV56103757; called by muse, mutect2, varscan2
- ADAMTS12 | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV100710432, COSV61271652; called by muse, mutect2, varscan2
- ADAMTS16 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV56999708; called by muse, mutect2, varscan2
- ADAMTS5 | c.1924G>T p.D642Y | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV53182296; called by muse, mutect2, varscan2
- ADAMTS8 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as COSV57295588; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2083G>C p.E695Q | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.424); catalogued as COSV55003356; called by muse, mutect2, varscan2
- ADCY1 | c.1813C>T p.Q605* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as COSV52033584; called by muse, mutect2, varscan2
- ADCY10 | c.1512G>C p.L504F | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV63243245; called by muse, mutect2, varscan2
- ADCY5 | c.3495C>G p.I1165M | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59201294; called by muse, mutect2, varscan2
- ADD1 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV53272111; called by muse, mutect2, varscan2
- ADD3 | c.1401G>A p.T467= | Splice Region (SNP) | VAF 19/39 reads (49%) | catalogued as rs755780836, COSV53324488; called by muse, mutect2, varscan2
- ADGRB1 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); catalogued as rs755062136, COSV60099729; called by muse, mutect2, varscan2
- ADGRB3 | c.2017G>C p.E673Q | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.815); catalogued as rs1258883783, COSV65409516; called by muse, mutect2, varscan2
- ADGRE2 | c.1104G>C p.Q368H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV59695215; called by muse, mutect2, varscan2
- ADGRF5 | c.2527C>A p.P843T | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV51934217, COSV51937653; called by muse, mutect2, varscan2
- ADGRG6 | c.1078C>G p.L360V | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.113); catalogued as COSV51597645; called by muse, mutect2, varscan2
- ADGRL3 | c.299G>C p.R100T (on ENST00000506720 / NM_001322402.2; = p.R32T on NM_015236.6) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV72270023; called by muse, mutect2
- ADGRL3 | c.2525C>A p.S842Y (on ENST00000506720 / NM_001322402.2; = p.S774Y on NM_015236.6) | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV72231375, COSV72232019; called by muse, mutect2, varscan2
- ADGRV1 | c.13303G>A p.D4435N | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV67991291; called by muse, mutect2, varscan2
- AGGF1 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as COSV57230459; called by muse, mutect2, varscan2
- AGPAT5 | c.908G>A p.R303K | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV53448433; called by muse, mutect2, varscan2
- AJUBA | c.1168G>C p.D390H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV52985567, COSV52986160; called by muse, mutect2, varscan2
- AJUBA | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 31/56 reads (55%) | catalogued as COSV52985018; called by muse, mutect2, varscan2
- AKAP13 | c.4072G>C p.D1358H | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63465098; called by muse, mutect2, varscan2
- AKR1D1 | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.603); catalogued as COSV54339205; called by muse, mutect2, varscan2
- AL121899.2 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV67349736, COSV67351744; called by muse, mutect2, varscan2
- AL592490.1 | c.639G>T p.Q213H | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV69427192, COSV69427241; called by muse, mutect2, varscan2
- ALDH16A1 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs746123884, COSV53195511; called by muse, mutect2, varscan2
- ALDH1L1 | c.1892C>G p.S631C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs142947117, COSV56417087, COSV56418529; called by muse, mutect2, varscan2
- ALDH8A1 | c.888G>C p.Q296H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.158); catalogued as COSV55643109, COSV99664610; called by muse, mutect2, varscan2
- ALDOA | c.587G>T p.G196V (on ENST00000642816 / NM_001243177.4; = p.G142V on NM_184041.5) | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs11553108; called by muse, mutect2, varscan2
- ALG9 | c.1585G>C p.D529H (on ENST00000614444 / NM_001352418.1; = p.D536H on NM_024740.2) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV67645107; called by muse, mutect2, varscan2
- ALPK1 | c.3169C>G p.Q1057E | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1560689836, COSV51589054; called by muse, varscan2
- ALPK2 | c.2696C>T p.S899L | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as rs1343132509, COSV64495041; called by muse, mutect2, varscan2
- AMDHD2 | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.777); catalogued as COSV53551731; called by muse, mutect2, varscan2
- ANK2 | c.10580C>T p.S3527L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as COSV52177139; called by muse, mutect2, varscan2
- ANK3 | c.10408G>C p.E3470Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV55055795; called by muse, mutect2, varscan2
- ANK3 | c.5237C>T p.S1746F | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.204); catalogued as rs754173928, COSV55071553, COSV55072795; called by muse, mutect2, varscan2
- ANKFN1 | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59441949, COSV59454344; called by muse, mutect2, varscan2
- ANKFY1 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1177246007, COSV58920284; called by muse, mutect2, varscan2
- ANKRD20A2P | c.2406G>C p.E802D | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.794); catalogued as COSV66464695; called by mutect2, varscan2
- ANKRD28 | c.1921G>C p.E641Q | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV67519443; called by muse, mutect2, varscan2
- ANKS1A | c.2014G>T p.E672* | Nonsense Mutation (SNP) | VAF 29/86 reads (34%) | catalogued as COSV64459109, COSV64462764; called by muse, mutect2, varscan2
- ANO1 | c.1360C>A p.P454T | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.898); catalogued as COSV60287438; called by muse, mutect2, varscan2
- ANO1 | c.2473G>A p.G825R | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs373835880, COSV62447811; called by muse, mutect2, varscan2
- AOAH | c.1258G>C p.D420H | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV51746887; called by muse, mutect2, varscan2
- AP2M1 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV53049362; called by muse, varscan2
- AP3D1 | c.2434G>A p.D812N | Missense Mutation (SNP) | VAF 48/63 reads (76%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.776); catalogued as rs1348846884, COSV61431170; called by muse, mutect2, varscan2
- AP4E1 | c.3110C>G p.S1037* | Nonsense Mutation (SNP) | VAF 7/10 reads (70%) | catalogued as COSV55918772; called by muse, mutect2, varscan2
- APC | c.3409G>A p.D1137N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.56); catalogued as COSV57332839, COSV57390518; called by muse, mutect2, varscan2
- APOB | c.9907G>A p.E3303K | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV51938884, COSV51955107; called by muse, mutect2, varscan2
- APOBR | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.234); catalogued as rs1032104599, COSV60492571; called by muse, mutect2, varscan2
- APOL3 | c.545G>T p.R182I (on ENST00000349314 / NM_145640.2; = p.R111I on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV62580439; called by muse, mutect2
- ARCN1 | c.843G>C p.K281N | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV50616341; called by muse, mutect2, varscan2
- ARHGAP11A | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as COSV64381409; called by muse, mutect2, varscan2
- ARHGAP32 | c.1638C>A p.F546L (on ENST00000310343 / NM_001378025.1; = p.F197L on NM_014715.4) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.262); catalogued as COSV59852720; called by muse, mutect2, varscan2
- ARHGAP4 | c.523C>G p.H175D | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV63132958, COSV63133366; called by muse, mutect2, varscan2
- ARHGAP5 | c.3944-1G>C p.X1315_splice (on ENST00000345122 / NM_001030055.2; = p.X1314_splice on NM_001173.3) | Splice Site (SNP) | VAF 19/44 reads (43%) | catalogued as COSV53735455; called by muse, mutect2, varscan2
- ARID1B | c.2176C>T p.P726S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.996); catalogued as COSV51673025; called by muse, mutect2, varscan2
- ARID4B | c.2771G>A p.R924Q | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated, low confidence (0.58); PolyPhen probably damaging (0.945); catalogued as rs1040035755, COSV99935933; called by muse, mutect2, varscan2
- ARID4B | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as COSV51601791, COSV51608104; called by muse, mutect2, varscan2
- ARMCX2 | c.1852G>A p.D618N | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100168219; called by muse, mutect2, varscan2
- ASPA | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.292); catalogued as COSV52153698; called by muse, mutect2, varscan2
- ASXL3 | c.3203G>T p.R1068L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52466416; called by muse, mutect2, varscan2
- ATAD3C | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV58022330; called by muse, mutect2, varscan2
- ATAD5 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); catalogued as COSV58977018; called by muse, mutect2, varscan2
- ATF7IP2 | c.1330C>T p.Q444* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as COSV61094589; called by muse, mutect2, varscan2
- ATG2B | c.4324C>G p.Q1442E | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV55891569; called by muse, mutect2, varscan2
- ATP10D | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV56710677; called by muse, mutect2, varscan2
- ATP2B2 | c.2759C>T p.T920M (on ENST00000352432; = p.T886M on NM_001683.5) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs368058047; called by muse, mutect2, varscan2
- ATP6V0D2 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV53413636, COSV53416476; called by muse, mutect2, varscan2
- ATP8B1 | c.3305C>A p.S1102* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV52178472, COSV52181140; called by muse, mutect2
- ATP8B2 | c.994G>A p.E332K (on ENST00000672630; = p.E299K on NM_001005855.2) | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as COSV59247602; called by muse, mutect2, varscan2
- ATXN2L | c.3088G>A p.E1030K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57375540; called by muse, varscan2
- AUTS2 | c.2318C>G p.S773* | Nonsense Mutation (SNP) | VAF 24/57 reads (42%) | catalogued as COSV61420201; called by muse, mutect2, varscan2
- AZI2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV55424837; called by muse, mutect2, varscan2
- B3GALT5 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58198442; called by muse, mutect2, varscan2
- BACH2 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV57601814; called by muse, mutect2, varscan2
- BAIAP3 | c.237G>C p.W79C | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.547); catalogued as COSV60982432; called by muse, mutect2, varscan2
- BAIAP3 | c.411G>C p.E137D | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs950097625, COSV100181472, COSV60982449; called by muse, mutect2, varscan2
- BARX2 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.053); catalogued as rs867138901, COSV55651649; called by muse, mutect2, varscan2
- BAZ2B | c.2162C>G p.S721C | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.547); catalogued as COSV58606274; called by muse, mutect2, varscan2
- BCAS4 | c.390C>G p.F130L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as COSV52813437; called by muse, varscan2
- BCL2L12 | c.133C>G p.R45G | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.03); catalogued as COSV55862547; called by muse, mutect2, varscan2
- BDP1 | c.2791G>A p.E931K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as rs748749374, COSV62433044; called by muse, mutect2, varscan2
- BDP1 | c.3958G>C p.E1320Q | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.33); catalogued as COSV62433051; called by muse, mutect2, varscan2
- BECN1 | c.1150G>C p.E384Q | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV59312461; called by muse, mutect2, varscan2
- BEST1 | c.1460C>G p.S487* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as COSV56445125; called by muse, mutect2, varscan2
- BICRAL | c.2060C>T p.S687L | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs143045076; called by muse, mutect2, varscan2
- BIN2 | c.1190G>C p.G397A | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); catalogued as COSV57207035; called by muse, mutect2, varscan2
- BNC2 | c.1409G>C p.R470P | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV66152919; called by muse, mutect2, varscan2
- BPIFB2 | c.1106C>G p.S369C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.905); catalogued as rs1418082923, COSV50063152, COSV50068181; called by muse, mutect2, varscan2
- BRCC3 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV57463581; called by muse, mutect2, varscan2
- BRD4 | c.1638G>C p.K546N | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.922); catalogued as rs761158744, COSV54582426; called by muse, varscan2
- BTBD11 | c.3128C>G p.S1043* (on ENST00000280758 / NM_001018072.2; = p.S580* on NM_001017523.2) | Nonsense Mutation (SNP) | VAF 21/47 reads (45%) | catalogued as COSV55023378, COSV55031784; called by muse, mutect2, varscan2
- BTBD7 | c.1765G>C p.E589Q | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV58288990, COSV58290541; called by muse, mutect2, varscan2
- BTBD8 | c.335G>C p.R112T | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as COSV61547238; called by muse, mutect2, varscan2
- BTRC | c.83C>G p.S28C | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV64560950, COSV64563471; called by muse, mutect2, varscan2
- BYSL | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as COSV54825666; called by muse, mutect2, varscan2
- C1QTNF7 | c.410G>C p.G137A | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54854642, COSV54856400; called by muse, mutect2, varscan2
- C1orf112 | c.1624G>C p.E542Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.595); catalogued as COSV53681265; called by muse, mutect2, varscan2
- C1orf116 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV63944422; called by muse, mutect2, varscan2
- C1orf116 | c.598C>G p.P200A | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV100847965, COSV63944593; called by muse, mutect2
- C20orf194 | c.2410G>C p.E804Q | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV52690674, COSV52700082; called by muse, mutect2, varscan2
- C2orf16 | c.2510C>T p.S837L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV62677256; called by muse, mutect2, varscan2
- C2orf16 | c.4571G>C p.R1524T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV62677259; called by muse, mutect2, varscan2
- C5orf22 | c.1246C>G p.Q416E | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs147146477; called by muse, mutect2, varscan2
- CA8 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV58773498; called by muse, mutect2
- CABCOCO1 | c.281G>C p.G94A | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57594604; called by muse, mutect2, varscan2
- CABIN1 | c.2506G>C p.E836Q | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV54086150; called by muse, mutect2, varscan2
- CABP2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs1391730624, COSV53709318; called by muse, mutect2, varscan2
- CACNA1A | c.6688G>A p.D2230N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs781749947, COSV64205884; called by muse, mutect2
- CACNB4 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52398964, COSV99138937; called by muse, mutect2, varscan2
- CALB1 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.307); catalogued as COSV55367582, COSV55368640; called by muse, mutect2, varscan2
- CALR | c.201G>C p.Q67H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV57131739; called by muse, mutect2, varscan2
- CAMSAP1 | c.1998G>C p.E666D | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56725720; called by muse, mutect2, varscan2
- CAPN13 | c.955G>C p.D319H | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54433218; called by muse, mutect2, varscan2
- CARS2 | c.1143G>A p.M381I | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV57284761, COSV57287712; called by muse, mutect2, varscan2
- CASKIN2 | c.2741C>G p.S914* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV58598493, COSV58598496; called by muse, mutect2, varscan2
- CASP4 | c.917C>G p.S306* | Nonsense Mutation (SNP) | VAF 27/63 reads (43%) | catalogued as COSV101274178; called by muse, mutect2, varscan2
- CASP8AP2 | c.4837G>A p.E1613K | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.88); catalogued as COSV52748751; called by muse, mutect2, varscan2
- CAVIN3 | c.631C>G p.R211G | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58269451; called by muse, mutect2, varscan2
- CCDC112 | c.270G>C p.Q90H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV65473653; called by muse, mutect2, varscan2
- CCDC124 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV71490513; called by muse, mutect2, varscan2
- CCDC183 | c.1188G>A p.M396I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1320944212, COSV61038395; called by muse, mutect2, varscan2
- CCDC87 | c.1348G>C p.D450H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV59579904; called by muse, mutect2, varscan2
- CCDC9B | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.93); catalogued as COSV66875821; called by muse, mutect2, varscan2
- CCRL2 | c.564C>G p.F188L | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV62193898, COSV62194109; called by muse, mutect2, varscan2
- CD109 | c.3476C>T p.S1159F | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV54653708; called by muse, mutect2, varscan2
- CD1B | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.322); catalogued as rs201728287; called by muse, mutect2, varscan2
- CD226 | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.348); catalogued as COSV54614546; called by muse, mutect2, varscan2
- CDC14A | c.864G>T p.L288F | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60555984; called by muse, mutect2, varscan2
- CDCA4 | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV60315900; called by muse, mutect2, varscan2
- CDCA4 | c.219G>A p.M73I | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60315910; called by muse, mutect2, varscan2
- CDH19 | c.1924G>A p.D642N | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.068); catalogued as COSV100052632, COSV50968425; called by muse, mutect2, varscan2
- CDK8 | c.1378C>G p.Q460E | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.953); catalogued as COSV67422063; called by muse, mutect2, varscan2
- CDKL3 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.895); catalogued as COSV54743594; called by muse, mutect2, varscan2
- CDRT1 | c.601C>G p.Q201E | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as COSV55412726; called by muse, mutect2, varscan2
- CELSR2 | c.389C>T p.T130I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV54776478; called by muse, mutect2, varscan2
- CELSR3 | c.8086-1G>C p.X2696_splice | Splice Site (SNP) | VAF 11/32 reads (34%) | catalogued as COSV50957361; called by muse, mutect2, varscan2
- CEP162 | c.1900G>C p.E634Q | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.067); catalogued as COSV57622294; called by muse, mutect2, varscan2
- CEP170 | c.954C>G p.D318E | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.493); catalogued as rs755921453, COSV60512089; called by muse, mutect2, varscan2
- CEP192 | c.5392C>G p.Q1798E | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58066687; called by muse, mutect2, varscan2
- CEP41 | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 38/42 reads (90%) | SIFT tolerated (0.67); PolyPhen benign (0.078); catalogued as COSV56220790; called by muse, mutect2, varscan2
- CEP57 | c.1494G>C p.W498C | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57689710; called by muse, mutect2, varscan2
- CEP72 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV53795366; called by muse, mutect2
- CEP89 | c.1137G>C p.E379D | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59866322; called by muse, mutect2, varscan2
- CEP95 | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56750473; called by muse, mutect2, varscan2
- CFAP20DC | c.1162G>C p.E388Q (on ENST00000482387 / NM_001351530.2; = p.E263Q on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.733); catalogued as COSV55924384; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.255); catalogued as COSV51593085; called by muse, mutect2, varscan2
- CFHR3 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.923); catalogued as COSV66402846; called by muse, mutect2, varscan2
- CGAS | c.1340C>T p.T447I | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as COSV64808657; called by muse, mutect2, varscan2
- CHD1 | c.4192G>A p.E1398K | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as COSV52342950; called by muse, mutect2, varscan2
- CHD3 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57876799; called by muse, varscan2
- CHD4 | c.4022-1G>C p.X1341_splice (on ENST00000357008 / NM_001363606.2; = p.X1354_splice on NM_001273.5) | Splice Site (SNP) | VAF 17/28 reads (61%) | catalogued as COSV58907082; called by muse, mutect2, varscan2
- CHRDL1 | c.190-1G>A p.X64_splice (on ENST00000372045; = p.X70_splice on NM_145234.4) | Splice Site (SNP) | VAF 13/36 reads (36%) | catalogued as COSV54327173; called by muse, mutect2, varscan2
- CHRNB3 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV51496554; called by muse, mutect2, varscan2
- CHRNE | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as COSV53419186; called by muse, mutect2, varscan2
- CLASP1 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.481); catalogued as COSV55332865; called by muse, mutect2, varscan2
- CLDN8 | c.512C>G p.T171R | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54526608; called by muse, mutect2, varscan2
- CLPTM1L | c.753C>G p.F251L | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV57990420; called by muse, mutect2
- CLTA | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54254725; called by muse, mutect2, varscan2
- CNOT9 | c.66C>G p.I22M | Missense Mutation (SNP) | VAF 72/87 reads (83%) | SIFT tolerated (0.18); PolyPhen benign (0.047); catalogued as COSV55301012; called by muse, mutect2, varscan2
- CNTN4 | c.2878C>T p.L960F | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754852308, COSV61877263; called by muse, mutect2, varscan2
- COA5 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.471); catalogued as COSV60831371; called by muse, mutect2, varscan2
- COL14A1 | c.1643C>G p.S548C | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.754); catalogued as COSV99919992; called by muse, mutect2, varscan2
- COL1A1 | c.4282G>C p.E1428Q | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1158203090, COSV56807899; called by muse, mutect2, varscan2
- COL2A1 | c.3583G>A p.E1195K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1186663188, COSV61527447; called by muse, mutect2, varscan2
- COL4A1 | c.3640C>T p.P1214S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.984); catalogued as COSV65429164; called by muse, mutect2, varscan2
- COL5A1 | c.1151C>G p.S384C | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as COSV65671274, COSV65672686; called by muse, mutect2, varscan2
- COL5A2 | c.3863C>T p.S1288L | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66412393; called by muse, mutect2, varscan2
- COL6A2 | c.2720C>T p.T907I | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV52427760; called by muse, mutect2
- COL7A1 | c.4000C>T p.R1334C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs141720633; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COLEC12 | c.1909G>A p.D637N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV68372435; called by muse, mutect2, varscan2
- COMMD7 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV54070914, COSV99640835; called by muse, mutect2
- COPA | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs769707936, COSV54106407; called by muse, mutect2, varscan2
- CPEB1 | c.938G>C p.R313T (on ENST00000617958; = p.R253T on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.288); catalogued as COSV55620386; called by muse, mutect2, varscan2
- CPLANE1 | c.8621G>A p.G2874D | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV57065550, COSV57066983; called by muse, mutect2, varscan2
- CPQ | c.1019G>C p.G340A | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV55154285; called by muse, mutect2, varscan2
- CPXM2 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV53858785; called by muse, mutect2, varscan2
- CREB3L1 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 44/60 reads (73%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.709); catalogued as COSV55832425; called by muse, mutect2, varscan2
- CREB5 | c.106C>T p.H36Y (on ENST00000357727 / NM_182898.4; = p.H29Y on NM_004904.3) | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV63225726; called by muse, mutect2, varscan2
- CREBBP | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.262); catalogued as rs1316551993, COSV52120803, COSV52134047; called by muse, mutect2, varscan2
- CREBBP | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs865788612, COSV52123131; called by muse, mutect2, varscan2
- CREBRF | c.1015C>G p.L339V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51634971; called by muse, mutect2, varscan2
- CSF1R | c.1092C>A p.F364L | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV53839679; called by muse, mutect2, varscan2
- CSMD1 | c.3972C>A p.F1324L (on ENST00000520002; = p.F1323L on NM_033225.6) | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV59304465, COSV59355574; called by muse, mutect2, varscan2
- CSNK1G3 | c.301C>G p.Q101E | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV62055963; called by muse, mutect2, varscan2
- CSPG4 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 99/239 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV57899085; called by muse, mutect2, varscan2
- CTSA | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV51943794, COSV51943971; called by muse, mutect2, varscan2
- CTSH | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.714); catalogued as COSV54985875; called by muse, mutect2, varscan2
- CUX1 | c.340G>A p.E114K (on ENST00000292535 / NM_181552.4; = p.E125K on NM_001913.5) | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV52908586; called by muse, mutect2, varscan2
- CUX2 | c.4318G>A p.D1440N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV55641369; called by muse, mutect2, varscan2
- CWC15 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.992); catalogued as rs1555095920, COSV54412138; called by muse, mutect2, varscan2
- CYP17A1 | c.59G>A p.R20K | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.94); PolyPhen benign (0.01); catalogued as COSV64005050; called by muse, mutect2, varscan2
- CYP24A1 | c.1195G>C p.D399H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53774028, COSV53775862; called by muse, mutect2, varscan2
- CYP2A6 | c.428G>C p.R143P | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs780336943, COSV56535165, COSV56536340; called by muse, varscan2
- CYP7A1 | c.1256C>G p.T419R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.16); catalogued as COSV56964697; called by muse, varscan2
- CYRIB | c.629C>G p.S210* | Nonsense Mutation (SNP) | VAF 19/89 reads (21%) | catalogued as COSV67829652, COSV67831737; called by muse, mutect2, varscan2
- DCAF12L2 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775259004, COSV63580943; called by muse, mutect2, varscan2
- DCDC2 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV65832874; called by muse, mutect2, varscan2
- DDX1 | c.1925G>A p.R642K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV51841919; called by muse, mutect2, varscan2
- DDX27 | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs771190820, COSV65609531; called by muse, mutect2, varscan2
- DDX60 | c.3925C>G p.Q1309E | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.216); catalogued as COSV67098144; called by muse, mutect2, varscan2
- DDX60 | c.2065G>C p.E689Q | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as COSV67098149; called by muse, mutect2, varscan2
- DEFB116 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as rs756559816, COSV68722321; called by muse, mutect2, varscan2
- DGKA | c.481C>G p.Q161E | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV59387339, COSV59387598; called by muse, mutect2, varscan2
- DGUOK | c.481C>G p.L161V | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as COSV51204343; called by muse, mutect2, varscan2
- DHX16 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 71/79 reads (90%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV64581433; called by muse, mutect2, varscan2
- DHX38 | c.957G>C p.Q319H | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV51699713; called by muse, mutect2, varscan2
- DMD | c.5812G>A p.E1938K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV63776908; called by muse, mutect2, varscan2
- DMKN | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV60088060; called by muse, mutect2, varscan2
- DMXL2 | c.6031G>C p.D2011H | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.173); catalogued as COSV51847213; called by muse, mutect2, varscan2
- DNAH1 | c.5332G>A p.E1778K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV70232973; called by muse, mutect2, varscan2
- DNAH10 | c.5518G>A p.E1840K (on ENST00000409039; = p.E1779K on NM_207437.3) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as COSV68998277; called by muse, mutect2, varscan2
- DNAH10 | c.12952C>G p.Q4318E (on ENST00000409039; = p.Q4257E on NM_207437.3) | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs771612024, COSV53020534, COSV53020924; called by muse, varscan2
- DNAH11 | c.3763G>C p.D1255H | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV60969327; called by muse, mutect2, varscan2
- DNAH2 | c.1679G>A p.R560K | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.94); PolyPhen benign (0.058); catalogued as COSV50018006, COSV99317792; called by muse, mutect2, varscan2
- DNAH7 | c.11057C>G p.S3686C | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.489); catalogued as COSV56776395; called by muse, mutect2, varscan2
- DNAH7 | c.5219C>T p.S1740F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752938822, COSV56776408; called by muse, mutect2, varscan2
- DNAH8 | c.3352G>A p.D1118N | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59467139; called by muse, mutect2, varscan2
- DNAH8 | c.10552C>G p.H3518D | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV59439596, COSV59467163; called by muse, mutect2, varscan2
- DNAJC18 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs764365674, COSV57416458; called by muse, varscan2
- DNAJC27 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as rs1442562481, COSV53096056; called by mutect2, varscan2
- DOCK1 | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV54750883; called by muse, mutect2, varscan2
- DOCK10 | c.6316G>T p.D2106Y | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as COSV51422245; called by muse, mutect2, varscan2
- DOCK11 | c.4529G>C p.R1510T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV52244216; called by muse, mutect2, varscan2
- DOCK6 | c.2257G>A p.V753M | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs375017238; called by muse, mutect2, varscan2
- DOCK9 | c.886C>T p.H296Y (on ENST00000376460 / NM_001366676.2; = p.H297Y on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as COSV59637640; called by muse, mutect2, varscan2
- DOP1B | c.6784G>A p.A2262T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV67690841; called by muse, mutect2, varscan2
- DPEP2 | c.368G>C p.R123T | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV52055264, COSV52055396; called by muse, mutect2, varscan2
- DPY30 | c.192C>G p.I64M | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV54459346; called by muse, mutect2, varscan2
- DSP | c.430C>G p.Q144E | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV65794337; called by muse, mutect2, varscan2
- DYNC1H1 | c.4400G>T p.R1467I | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV64139906; called by muse, mutect2, varscan2
- DYNC1I2 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV55528279; called by muse, mutect2, varscan2
- E2F3 | c.473G>A p.R158K | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.066); catalogued as COSV60898914; called by muse, mutect2, varscan2
- EEF1E1 | c.110A>G p.N37S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1479300832, COSV65675888; called by mutect2, varscan2
- EFCAB5 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs756152333, COSV57933906; called by muse, mutect2, varscan2
- EIF3B | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.788); catalogued as COSV62804209; called by muse, mutect2, varscan2
- EIF3D | c.984G>C p.L328F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53404472; called by muse, mutect2, varscan2
- EIF4B | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 34/71 reads (48%) | catalogued as COSV50405642; called by muse, mutect2, varscan2
- EMCN | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 39/93 reads (42%) | catalogued as COSV56461927; called by muse, mutect2, varscan2
- EML4 | c.599C>G p.S200* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as COSV59302212; called by muse, mutect2, varscan2
- ENAH | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.874); catalogued as COSV52870519; called by muse, mutect2, varscan2
- EP300 | c.56C>G p.S19* | Nonsense Mutation (SNP) | VAF 20/54 reads (37%) | catalogued as COSV54339696; called by muse, mutect2, varscan2
- EP300 | c.842C>G p.S281* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV54339708, COSV99609302; called by muse, mutect2, varscan2
- EPC2 | c.304C>G p.H102D | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV104384556, COSV51547137; called by muse, mutect2, varscan2
- EPN3 | c.1220G>C p.G407A | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as COSV52141795; called by muse, mutect2, varscan2
- EPPK1 | c.3896C>T p.S1299L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs1554660317, COSV73262033; called by muse, mutect2
- ERBB2 | c.1203G>C p.E401D | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV54077143, COSV54080592; called by muse, mutect2, varscan2
- ERBIN | c.3860G>C p.R1287T (on ENST00000284037 / NM_001253697.2; = p.R1246T on NM_018695.4) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52322718; called by muse, mutect2, varscan2
- ERI2 | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs1285724779, COSV55501273; called by muse, mutect2, varscan2
- ERP29 | c.549G>C p.Q183H | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs759534955, COSV55674137; called by muse, mutect2, varscan2
- ETNK2 | c.784G>C p.G262R | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV65819996; called by muse, mutect2, varscan2
- EVC | c.1519G>C p.E507Q | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.117); catalogued as COSV53833008, COSV53836029; called by muse, mutect2, varscan2
- EVI5L | c.1723G>C p.E575Q | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.575); catalogued as COSV54487478; called by muse, mutect2
- EYS | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs1435131611, COSV60994522; called by muse, mutect2, varscan2
- F8 | c.503C>G p.S168C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); catalogued as COSV64276654, COSV64278110; called by muse, mutect2, varscan2
- FAM107A | c.315G>C p.Q105H | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV62980998; called by muse, mutect2, varscan2
- FAM107B | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.015); catalogued as rs767743814, COSV51689663; called by muse, mutect2, varscan2
- FAM126A | c.1094C>G p.S365* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as COSV69472225; called by muse, mutect2, varscan2
- FAM13C | c.523G>C p.V175L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV104375106, COSV53252810; called by muse, mutect2, varscan2
- FAM162B | c.177G>C p.E59D | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV63920580; called by muse, mutect2, varscan2
- FAM193A | c.2894C>A p.S965Y | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV61196867; called by muse, mutect2, varscan2
- FAM222B | c.251C>G p.S84* | Nonsense Mutation (SNP) | VAF 44/109 reads (40%) | catalogued as COSV57932586, COSV57933077; called by muse, mutect2, varscan2
- FAM234A | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV51453478; called by muse, mutect2, varscan2
- FAM91A1 | c.850-1G>A p.X284_splice | Splice Site (SNP) | VAF 36/69 reads (52%) | catalogued as COSV58238475; called by muse, mutect2, varscan2
- FAM98A | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.25); catalogued as COSV53211259; called by muse, mutect2, varscan2
- FANCA | c.3928G>C p.E1310Q | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV57070985, COSV57073895; called by muse, mutect2, varscan2
- FANCD2 | c.65-1G>C p.X22_splice | Splice Site (SNP) | VAF 27/64 reads (42%) | catalogued as COSV55043074; called by muse, mutect2, varscan2
- FAT2 | c.4277C>T p.S1426F | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV55825530; called by muse, mutect2, varscan2
- FAT3 | c.12334T>A p.S4112T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV53148758; called by muse, mutect2, varscan2
- FBN2 | c.2200G>C p.D734H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as COSV52515230, COSV52531628; called by muse, mutect2, varscan2
- FBXO38 | c.2176G>A p.D726N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.033); catalogued as rs548894296, COSV57029894; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXO46 | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV58349329; called by muse, mutect2, varscan2
- FCHSD1 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51838246; called by muse, mutect2, varscan2
- FGA | c.2512G>C p.E838Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV57398725; called by muse, mutect2, varscan2
- FGD2 | c.1570G>C p.E524Q | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs773635309, COSV51465129; called by muse, mutect2, varscan2
- FHOD1 | c.3331C>G p.L1111V | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV50765091; called by muse, mutect2, varscan2
- FIG4 | c.1591G>C p.E531Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57789641; called by muse, mutect2, varscan2
- FIGNL2 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV73729274; called by muse, mutect2, varscan2
- FLG | c.2975G>A p.R992K | Missense Mutation (SNP) | VAF 100/256 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs753330086, COSV64242777; called by muse, mutect2, varscan2
- FLNA | c.6392C>A p.S2131Y (on ENST00000369850 / NM_001110556.2; = p.S2123Y on NM_001456.3) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV61048086; called by muse, varscan2
- FLNA | c.5725G>C p.E1909Q (on ENST00000369850 / NM_001110556.2; = p.E1901Q on NM_001456.3) | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV61048101; called by muse, mutect2, varscan2
- FLT1 | c.3058C>T p.H1020Y | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1156761371, COSV56735757; called by muse, mutect2, varscan2
- FMNL3 | c.1132G>A p.V378M | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV53297583; called by muse, mutect2, varscan2
- FMR1 | c.533C>G p.S178* | Nonsense Mutation (SNP) | VAF 20/61 reads (33%) | catalogued as COSV54426049; called by muse, mutect2, varscan2
- FNDC3B | c.1054C>T p.H352Y | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV61046686; called by muse, mutect2, varscan2
- FNIP2 | c.1687G>C p.E563Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52443301; called by muse, mutect2, varscan2
- FOCAD | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs1346482371, COSV58104616; called by muse, mutect2, varscan2
- FOXF1 | c.1122C>G p.I374M | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV52287650; called by muse, mutect2, varscan2
- FOXP1 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV59548840; called by muse, mutect2, varscan2
- FRS3 | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 26/69 reads (38%) | catalogued as COSV99442966; called by muse, mutect2, varscan2
- FSTL3 | c.780G>C p.E260D | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV51261832; called by muse, mutect2, varscan2
- FYN | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV57618012; called by muse, mutect2, varscan2
- FZD4 | c.1563G>C p.K521N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV72294585; called by muse, mutect2, varscan2
- GABRA2 | c.1019G>C p.R340T | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62917407; called by muse, mutect2, varscan2
- GABRG3 | c.339G>C p.M113I | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as COSV61510850, COSV61526145; called by muse, mutect2, varscan2
- GALNT17 | c.1232C>G p.S411C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); catalogued as COSV61177970; called by muse, mutect2, varscan2
- GALNT7 | c.1837-1G>A p.X613_splice | Splice Site (SNP) | VAF 10/43 reads (23%) | catalogued as COSV53933110; called by muse, mutect2, varscan2
- GBF1 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV64147363; called by muse, mutect2, varscan2
- GBF1 | c.1822G>C p.E608Q (on ENST00000369983 / NM_001377137.1; = p.E607Q on NM_004193.3) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.437); catalogued as COSV64147371; called by muse, mutect2, varscan2
- GBP3 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.071); catalogued as COSV52519275; called by muse, mutect2, varscan2
- GCKR | c.1873C>T p.Q625* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV53110051; called by muse, mutect2, varscan2
- GCNA | c.1953G>A p.T651= | Splice Region (SNP) | VAF 16/81 reads (20%) | catalogued as COSV65461844; called by muse, mutect2, varscan2
- GEM | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV52597958, COSV52598167; called by muse, mutect2, varscan2
- GEMIN5 | c.2950C>T p.H984Y | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs768016683, COSV53563095; called by muse, mutect2, varscan2
- GHR | c.1279G>C p.D427H | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV50121920; called by muse, mutect2, varscan2
- GIPC1 | c.766C>G p.L256V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52875933; called by muse, mutect2, varscan2
- GJA8 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0.011); catalogued as rs145727273; called by muse, mutect2, varscan2
- GLOD5 | c.234G>C p.Q78H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57489764; called by muse, mutect2, varscan2
- GNE | c.154G>C p.D52H (on ENST00000396594 / NM_001128227.3; = p.D21H on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV64952544; called by muse, mutect2, varscan2
- GNPTAB | c.2465C>T p.T822I | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV68449813; called by muse, mutect2, varscan2
- GNPTAB | c.1406C>G p.S469C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.421); catalogued as COSV100172506, COSV68449815; called by muse, mutect2, varscan2
- GOLGA1 | c.34G>C p.E12Q | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60615562; called by muse, mutect2, varscan2
- GOLGA5 | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 27/56 reads (48%) | catalogued as COSV50834235; called by muse, mutect2, varscan2
- GOLGA6L9 | c.912G>C p.E304D | Missense Mutation (SNP) | VAF 44/278 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as rs1321179936; called by muse, varscan2
- GOLGA7B | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV54006284; called by muse, mutect2, varscan2
- GON4L | c.4539A>T p.E1513D | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55199059; called by muse, varscan2
- GON4L | c.4441G>C p.E1481Q | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV55199081; called by muse, mutect2, varscan2
- GP9 | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV56624540; called by muse, mutect2, varscan2
- GPATCH3 | c.1312G>C p.E438Q | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV64652451, COSV64653074; called by muse, mutect2, varscan2
- GPC6 | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as COSV65524707; called by muse, mutect2, varscan2
- GPIHBP1 | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.723); catalogued as CD1414689, COSV58209453; called by muse, mutect2, varscan2
- GPR151 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.062); catalogued as COSV57039934; called by muse, mutect2, varscan2
- GPR153 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.171); catalogued as COSV100928514, COSV64938793; called by muse, mutect2
- GPR171 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.64); catalogued as COSV56388939; called by muse, mutect2, varscan2
- GPR176 | c.1171G>C p.E391Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV54447017; called by muse, mutect2, varscan2
- GPRIN3 | c.725C>G p.S242C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV60885718; called by muse, mutect2, varscan2
- GPSM2 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as COSV51443756; called by muse, mutect2, varscan2
- GRAMD2A | c.957G>A p.L319= | Splice Region (SNP) | VAF 14/38 reads (37%) | catalogued as COSV59034565; called by muse, mutect2, varscan2
- GRHL2 | c.1854C>A p.F618L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV52552102; called by muse, mutect2, varscan2
- GRIA3 | c.384C>G p.S128R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52072819; called by muse, mutect2, varscan2
- GRIA4 | c.1040G>A p.R347K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as COSV56906558; called by muse, mutect2, varscan2
- GRIK1 | c.2713G>C p.E905Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.076); catalogued as COSV58726351; called by muse, mutect2, varscan2
- GRIN2B | c.3683C>T p.T1228M | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as rs75670883, COSV74206966; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIP1 | c.2760G>C p.L920F (on ENST00000359742 / NM_001379345.1; = p.L868F on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as COSV54015865, COSV54034289; called by muse, mutect2, varscan2
- GRIP1 | c.1987G>C p.E663Q (on ENST00000359742 / NM_001379345.1; = p.E611Q on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV54034355; called by muse, varscan2
- GRK4 | c.188G>A p.G63E (on ENST00000398052 / NM_182982.3; = p.G31E on NM_005307.3) | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61670379; called by muse, mutect2, varscan2
- GSTA3 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as COSV52980288, COSV52981173; called by mutect2, varscan2
- GTPBP1 | c.835-1G>C p.X279_splice | Splice Site (SNP) | VAF 17/30 reads (57%) | catalogued as COSV53286696; called by muse, mutect2, varscan2
- GUCY1A1 | c.1079C>G p.S360C | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.684); catalogued as COSV56651285, COSV56654554; called by muse, mutect2, varscan2
- GXYLT1 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as COSV55140031; called by muse, mutect2, varscan2
- H2AC16 | c.89G>C p.R30P | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58900822; called by muse, mutect2, varscan2
- H2AC20 | c.89G>C p.R30P | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1553759878, COSV58611399, COSV58611757; called by muse, mutect2, varscan2
- H2AW | c.122C>G p.S41W | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs1223770030, COSV100797310, COSV64209970; called by muse, mutect2, varscan2
- H4C2 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.485); catalogued as rs142718461; called by muse, mutect2
- HAP1 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as COSV57879695; called by muse, mutect2, varscan2
- HAUS4 | c.773C>G p.S258C | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52827904; called by muse, mutect2, varscan2
- HDAC11 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV55474109; called by muse, mutect2, varscan2
- HDAC3 | c.1271G>A p.S424N | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV53886101; called by muse, mutect2, varscan2
- HEATR4 | c.599G>C p.R200T | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.518); catalogued as COSV58575495; called by muse, mutect2, varscan2
- HELB | c.2305C>G p.Q769E | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV56074965; called by muse, mutect2, varscan2
- HELB | c.3237C>G p.F1079L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV56074974; called by muse, mutect2, varscan2
- HERC2 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.548); catalogued as COSV55319066, COSV55332717; called by muse, mutect2, varscan2
- HGFAC | c.1867G>A p.G623R | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375925462; called by muse, mutect2, varscan2
- HIF3A | c.214G>A p.A72T (on ENST00000377670 / NM_152795.4; = p.P51= on NM_022462.4) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as COSV52198318; called by muse, mutect2, varscan2
- HIVEP2 | c.6854G>A p.R2285Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs894058552, COSV50031347; called by muse, mutect2, varscan2
- HLA-B | c.896-1G>A p.X299_splice | Splice Site (SNP) | VAF 67/83 reads (81%) | catalogued as COSV69520575, COSV69520821; called by muse, mutect2, varscan2
- HLCS | c.1833C>G p.I611M | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV60796116; called by muse, mutect2, varscan2
- HMCN1 | c.16540G>T p.G5514W | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54922693, COSV99630489; called by muse, mutect2, varscan2
- HMGB2 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.199); catalogued as COSV56633251; called by muse, mutect2, varscan2
- HMGCR | c.2440C>T p.Q814* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV55315597; called by muse, mutect2, varscan2
- HOATZ | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as rs763085620, COSV100239525, COSV60442073; called by muse, mutect2, varscan2
- HOXA3 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs764656757, COSV57824928; called by muse, mutect2, varscan2
- HOXC11 | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.356); catalogued as COSV54533786; called by muse, mutect2
- HS6ST3 | c.1095G>C p.E365D | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100941058, COSV65001807; called by muse, mutect2, varscan2
- HSD17B4 | c.395C>T p.S132F (on ENST00000414835 / NM_001199291.3; = p.S107F on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 91/248 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV56335139; called by muse, mutect2
- HSD17B6 | c.669G>C p.M223I | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV59108419; called by muse, mutect2, varscan2
- HSP90B1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.69); PolyPhen benign (0.011); catalogued as COSV100236658; called by muse, mutect2, varscan2
- HSPA2 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.192); catalogued as rs765920858, COSV55970768; called by muse, mutect2, varscan2
- HTR1B | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV64051724; called by muse, mutect2, varscan2
- HTR3A | c.1225C>T p.R409W | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs746743815, COSV55470741, COSV55471627; called by muse, mutect2, varscan2
- HTR6 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV57034015; called by muse, mutect2, varscan2
- HUWE1 | c.13069C>T p.R4357C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53356962; called by muse, mutect2, varscan2
- HUWE1 | c.7497C>G p.F2499L | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV53356985; called by muse, mutect2, varscan2
- HUWE1 | c.7306G>A p.E2436K | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.424); catalogued as COSV53357003; called by muse, mutect2, varscan2
- HUWE1 | c.995C>G p.T332R | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53357023; called by muse, mutect2, varscan2
- HYDIN | c.4921G>C p.E1641Q | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV59264652; called by muse, mutect2, varscan2
- IBTK | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV60394851; called by muse, mutect2, varscan2
- IFT81 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV54364998; called by muse, mutect2, varscan2
- IGSF10 | c.4373G>C p.R1458T | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV56789231; called by muse, mutect2, varscan2
- IK | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as rs745401397, COSV70258061; called by muse, mutect2, varscan2
- IL33 | c.784A>T p.N262Y | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV67343433; called by muse, mutect2, varscan2
- IL6R | c.572C>G p.S191C | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV59818119; called by muse, mutect2, varscan2
- INO80 | c.3817G>A p.E1273K | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62738340; called by muse, mutect2, varscan2
- INPPL1 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs1200716611, COSV53357767, COSV99995687; called by muse, mutect2, varscan2
- INPPL1 | c.938A>T p.E313V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV53357775; called by muse, mutect2, varscan2
- INSR | c.3722C>G p.S1241C | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV57168748; called by muse, mutect2, varscan2
- IQCE | c.363G>C p.K121N | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as rs775017409, COSV100383572; called by muse, mutect2, varscan2
- IQGAP2 | c.1098G>C p.L366F | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV57177877; called by muse, mutect2, varscan2
- ITGA11 | c.2347G>C p.E783Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.078); catalogued as COSV100242123, COSV59880288; called by muse, mutect2, varscan2
- ITGA7 | c.1043G>A p.R348H (on ENST00000555728; = p.R304H on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs768455364, COSV57691147; called by muse, mutect2, varscan2
- ITGA9 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs374117373; called by muse, mutect2, varscan2
- ITGAM | c.473C>G p.S158C | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54935759, COSV54940074; called by muse, mutect2, varscan2
- ITGAX | c.877C>G p.Q293E | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV51648998; called by muse, mutect2, varscan2
- ITGB7 | c.532delinsTT p.L178Ffs*82 | Frame Shift Ins (INS) | VAF 18/47 reads (38%) | catalogued as COSV57239642; called by mutect2*, pindel, varscan2*
- ITIH2 | c.1164C>G p.I388M | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV64434355; called by muse, mutect2, varscan2
- ITPR2 | c.1630C>G p.Q544E | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV67272356; called by muse, mutect2, varscan2
- IYD | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV57602842, COSV57604565; called by muse, mutect2, varscan2
- JADE2 | c.2211G>C p.E737D | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV50914510, COSV50924249; called by muse, mutect2, varscan2
- JTB | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV55132889; called by muse, mutect2, varscan2
- JUNB | c.879C>G p.I293M | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56878245, COSV56878450; called by muse, mutect2, varscan2
- KATNA1 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.434); catalogued as COSV59503486; called by muse, mutect2, varscan2
- KATNA1 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59503494; called by muse, mutect2, varscan2
- KATNIP | c.2120C>G p.S707W | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV55172870, COSV55187526; called by muse, mutect2, varscan2
- KAZN | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.678); catalogued as rs773002622, COSV63207903; called by muse, mutect2, varscan2
- KBTBD12 | c.1812G>A p.M604I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV59679343; called by muse, mutect2, varscan2
- KCNJ12 | c.790C>G p.L264V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59162488, COSV59170521; called by muse, mutect2, varscan2
- KCNMB4 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV50692408; called by muse, mutect2, varscan2
- KCNT1 | c.1831G>A p.E611K (on ENST00000488444; = p.E630K on NM_020822.3) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV53706746; called by muse, mutect2, varscan2
- KCNU1 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV67758376; called by muse, mutect2, varscan2
- KDM1B | c.2179G>A p.D727N (on ENST00000449850; = p.D494N on NM_153042.4) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs1426006729, COSV52813164; called by muse, mutect2, varscan2
- KDM3B | c.4412-1G>C p.X1471_splice | Splice Site (SNP) | VAF 15/40 reads (38%) | catalogued as COSV58693300; called by muse, mutect2, varscan2
- KDM4B | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.26); PolyPhen benign (0.364); catalogued as rs770149637, COSV50217201; called by muse, mutect2, varscan2
- KIAA0930 | c.610C>T p.Q204* (on ENST00000336156 / NM_001009880.2; = p.Q209* on NM_015264.2) | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as COSV52662683, COSV52663997; called by muse, mutect2, varscan2
- KIAA1109 | c.2343G>C p.W781C | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV52684948; called by muse, mutect2, varscan2
- KIF1B | c.4703C>T p.S1568L (on ENST00000377086 / NM_001365952.1; = p.S1522L on NM_015074.3) | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV55812577; called by muse, mutect2, varscan2
- KIF20A | c.1606G>C p.E536Q | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as COSV67510319; called by muse, mutect2, varscan2
- KIF20B | c.5048C>G p.P1683R (on ENST00000371728 / NM_001284259.2; = p.P1643R on NM_016195.4) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs373257085; called by muse, mutect2, varscan2
- KIF26B | c.553G>C p.D185H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV68572444, COSV68572597; called by mutect2, varscan2
- KIF4A | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65544732; called by muse, mutect2, varscan2
- KIF5B | c.650C>G p.T217R | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.519); catalogued as COSV56654634; called by muse, mutect2, varscan2
- KIFBP | c.1213G>C p.E405Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.131); catalogued as COSV62832131; called by muse, mutect2, varscan2
- KIFBP | c.1452G>C p.M484I | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV100741438, COSV62832137; called by muse, mutect2, varscan2
- KIFBP | c.1844G>A p.R615K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.191); catalogued as COSV62832143; called by muse, mutect2
- KLF5 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100890594, COSV66615042; called by muse, mutect2, varscan2
- KLF9 | c.293A>C p.D98A | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65807957; called by muse, mutect2, varscan2
- KLHDC7A | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV68770484; called by muse, mutect2, varscan2
- KLHL11 | c.1844G>C p.G615A | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV59862664; called by muse, mutect2, varscan2
- KLK5 | c.529C>G p.H177D | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV60451054; called by muse, mutect2, varscan2
- KMT2C | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV51475002; called by muse, mutect2, varscan2
- KNDC1 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.962); catalogued as rs778600479, COSV58842713; called by muse, mutect2, varscan2
- KNTC1 | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV61082411; called by muse, mutect2, varscan2
- KRT5 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs182482982, COSV52863072; called by muse, mutect2, varscan2
- KRT5 | c.1540G>A p.G514R | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.265); catalogued as COSV52862260; called by muse, mutect2, varscan2
- KRT71 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57292142; called by muse, mutect2, varscan2
- KRTAP10-4 | c.1067G>A p.R356K | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV59960905; called by muse, mutect2, varscan2
- KTI12 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV65406009; called by muse, mutect2, varscan2
- KTN1 | c.1693G>C p.E565Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV68024784; called by muse, mutect2, varscan2
- LACTB | c.1140G>C p.K380N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.09); catalogued as COSV56056572; called by muse, mutect2, varscan2
- LAMA4 | c.2932G>A p.E978K (on ENST00000230538 / NM_001105206.3; = p.E971K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV57894464; called by muse, mutect2, varscan2
- LATS1 | c.751C>G p.P251A | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.355); catalogued as rs1161379405, COSV53596052; called by muse, varscan2
- LATS1 | c.673C>G p.Q225E | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV53595844; called by muse, varscan2
- LBR | c.979C>G p.L327V | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV55290630; called by muse, mutect2, varscan2
- LCE1A | c.332G>T p.*111Lext*6 | Nonstop Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV58727763; called by muse, mutect2, varscan2
- LCN8 | c.404G>A p.R135Q (on ENST00000612714 / NM_001345934.1; = p.R112Q on NM_178469.3) | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs572429888, COSV60210808; called by muse, mutect2, varscan2
- LCTL | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58422680; called by muse, mutect2, varscan2
- LGALS3 | c.594C>G p.F198L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54306057; called by muse, mutect2, varscan2
- LGR4 | c.1953G>C p.M651I | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV60821328; called by muse, mutect2, varscan2
- LIN9 | c.856G>A p.E286K (on ENST00000366808 / NM_001270410.2; = p.E231K on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.517); catalogued as COSV60245650; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.217A>G p.I73V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as COSV53282673; called by muse, mutect2, varscan2
- LINGO4 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.474); catalogued as COSV59094567; called by muse, mutect2, varscan2
- LLGL1 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV57499597; called by muse, mutect2, varscan2
- LMLN | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs147639153; called by muse, mutect2, varscan2
- LMTK2 | c.1531G>C p.E511Q | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.189); catalogued as COSV52000435; called by muse, mutect2, varscan2
- LMTK3 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.435); catalogued as rs762684501, COSV54315391; called by muse, mutect2, varscan2
- LNPEP | c.2366C>G p.S789* | Nonsense Mutation (SNP) | VAF 42/112 reads (38%) | catalogued as COSV51479776; called by muse, mutect2, varscan2
- LONRF2 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV66541621; called by muse, mutect2
- LRGUK | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1198401966, COSV53641191; called by muse, mutect2, varscan2
- LRP1B | c.11942G>A p.G3981E | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV67252616; called by muse, mutect2, varscan2
- LRP2 | c.11644C>T p.P3882S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as COSV55565046; called by muse, mutect2, varscan2
- LRRC29 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as rs769879346, COSV58527879; called by muse, mutect2, varscan2
- LRRC40 | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as COSV63942824; called by muse, mutect2, varscan2
- LRRC42 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs749346484, COSV59961031, COSV59961486; called by muse, mutect2, varscan2
- LRRK1 | c.3383C>G p.S1128* | Nonsense Mutation (SNP) | VAF 28/56 reads (50%) | catalogued as COSV52621465; called by muse, mutect2, varscan2
- LRRK2 | c.7372A>G p.M2458V | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs1473496150, COSV54162819; called by muse, mutect2, varscan2
- LRRN2 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65784385; called by muse, mutect2, varscan2
- LRRN4 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 17/81 reads (21%) | catalogued as COSV66646175, COSV66646358; called by muse, mutect2, varscan2
- LTN1 | c.3877C>G p.L1293V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100798084, COSV63734667; called by muse, mutect2, varscan2
- LY9 | c.104C>G p.S35C | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV54436125; called by muse, mutect2, varscan2
- MACF1 | c.14797G>C p.E4933Q (on ENST00000372915; = p.E2866Q on NM_012090.5) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV57133738; called by muse, mutect2, varscan2
- MADD | c.3645G>C p.L1215F | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV60627457; called by muse, mutect2, varscan2
- MADD | c.4243G>C p.E1415Q | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.501); catalogued as COSV60627472; called by muse, mutect2, varscan2
- MAEL | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.714); catalogued as COSV63305780; called by muse, mutect2, varscan2
- MAF1 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.02); catalogued as COSV59363713; called by muse, mutect2, varscan2
- MAGEB16 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.069); catalogued as COSV101303258, COSV67874280; called by muse, mutect2, varscan2
- MAGIX | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.695); catalogued as COSV66256348; called by muse, mutect2, varscan2
- MAGOH | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV65161376; called by muse, mutect2, varscan2
- MAN1A1 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV63782072; called by muse, mutect2, varscan2
- MAN2B1 | c.2831C>G p.S944C | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV55473801; called by muse, mutect2, varscan2
- MAN2B1 | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.019); catalogued as rs1303843843, COSV55473809; called by muse, mutect2, varscan2
- MAN2B2 | c.2211G>C p.Q737H | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53455390; called by muse, mutect2, varscan2
- MAOB | c.207G>C p.L69F | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.716); catalogued as COSV65206312; called by muse, mutect2, varscan2
- MAP1B | c.5198C>G p.S1733C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV99702662; called by muse, mutect2, varscan2
- MAP4K5 | c.2385C>G p.F795L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.995); catalogued as COSV50157628; called by muse, mutect2, varscan2
- MARCHF6 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV56883651, COSV56884445; called by muse, mutect2, varscan2
- MARK4 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53461647; called by muse, mutect2, varscan2
- MATN3 | c.320C>G p.S107C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.907); catalogued as COSV68100342; called by muse, mutect2, varscan2
- MCF2L | c.2855G>C p.R952T (on ENST00000375608; = p.R920T on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV56179926; called by muse, mutect2, varscan2
- MDM1 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as rs200011845, COSV57446860, COSV57447915; called by muse, mutect2, varscan2
- MDN1 | c.6902G>A p.R2301Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65526332; called by muse, mutect2, varscan2
- MED17 | c.1046C>G p.S349* | Nonsense Mutation (SNP) | VAF 23/55 reads (42%) | catalogued as COSV52599283; called by muse, mutect2, varscan2
- MED22 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV59299190; called by muse, mutect2, varscan2
- MED25 | c.1864C>T p.P622S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); catalogued as COSV57206173; called by muse, mutect2, varscan2
- MFAP3 | c.552C>G p.I184M | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59456963; called by muse, mutect2
- MFAP3 | c.913C>G p.L305V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV59456974; called by muse, mutect2, varscan2
- MFNG | c.660C>G p.F220L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100812855, COSV63690644; called by muse, mutect2, varscan2
- MGAT4C | c.584G>C p.R195T | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59835597; called by muse, mutect2, varscan2
- MIB1 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV55092952; called by muse, mutect2, varscan2
- MIEN1 | c.125T>C p.L42P | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54077146; called by muse, mutect2, varscan2
- MKNK2 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 23/43 reads (53%) | catalogued as COSV51734122; called by muse, mutect2, varscan2
- MLKL | c.753C>G p.I251M | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs972047824, COSV100087393; called by muse, mutect2, varscan2
- MMP1 | c.533G>C p.G178A | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV59511117; called by muse, mutect2, varscan2
- MMP19 | c.1271G>C p.G424A | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV59452344; called by muse, mutect2, varscan2
- MMP27 | c.676C>G p.H226D | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52781950; called by muse, mutect2, varscan2
- MOV10L1 | c.738G>C p.K246N | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV53176209; called by muse, mutect2, varscan2
- MPP5 | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as rs1408001970, COSV55531280; called by muse, mutect2, varscan2
- MPPE1 | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57883171; called by muse, mutect2, varscan2
- MROH2B | c.2152C>G p.L718V | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68187272; called by muse, mutect2, varscan2
- MROH2B | c.1738G>C p.E580Q | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV68187276; called by muse, mutect2, varscan2
- MS4A14 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.425); catalogued as COSV55736688; called by muse, mutect2, varscan2
- MTREX | c.167C>G p.S56* | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | catalogued as COSV57928399; called by muse, mutect2, varscan2
- MTSS2 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.39); PolyPhen benign (0.102); catalogued as rs770157588, COSV55381939; called by muse, mutect2, varscan2
- MUC4 | c.1510G>C p.E504Q | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.413); catalogued as COSV62158638, COSV62171568; called by muse, mutect2, varscan2
- MUC4 | c.568G>C p.D190H | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV62171577; called by muse, mutect2, varscan2
- MYBL2 | c.540C>G p.I180M | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.765); catalogued as rs749689985, COSV53829569; called by muse, mutect2, varscan2
- MYCBP2 | c.13012G>C p.D4338H (on ENST00000357337; = p.D4376H on NM_015057.5) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62031101; called by muse, mutect2, varscan2
- MYH7 | c.5520G>C p.M1840I | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100805972, COSV62521794; called by muse, mutect2, varscan2
- MYH9 | c.1811C>T p.S604F | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV53390596, COSV53392065; called by muse, mutect2, varscan2
- MYL12A | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as COSV54182489, COSV99470269; called by muse, mutect2, varscan2
- MYL6B | c.508C>G p.L170V | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52879360; called by muse, mutect2, varscan2
- MYO10 | c.1708G>A p.D570N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV72563200; called by muse, mutect2, varscan2
- MYO1E | c.173C>G p.S58* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as COSV55691880; called by muse, varscan2
- MYO9A | c.6652C>G p.L2218V | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV61854792; called by muse, mutect2, varscan2
- MYT1 | c.2465C>T p.S822F | Missense Mutation (SNP) | VAF 84/130 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV60500793, COSV60510342; called by muse, mutect2, varscan2
- MZF1 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as rs1286094326, COSV53042526; called by muse, mutect2
- MZF1 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV53042537; called by muse, mutect2, varscan2
- N4BP2 | c.3085G>C p.E1029Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54704881; called by muse, mutect2, varscan2
- NADSYN1 | c.280A>T p.N94Y | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV59813944; called by muse, mutect2, varscan2
- NAT10 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as COSV57665437; called by muse, mutect2, varscan2
- NAT2 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54062589; called by muse, mutect2, varscan2
- NAV1 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.79); catalogued as COSV55216264; called by muse, mutect2, varscan2
- NAV1 | c.2589G>C p.M863I | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.103); catalogued as COSV55222226; called by muse, mutect2, varscan2
- NAV1 | c.2754G>C p.E918D | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV55222234; called by muse, mutect2, varscan2
- NAV1 | c.5590G>A p.D1864N | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV55222246; called by muse, mutect2, varscan2
- NBEA | c.5078C>A p.T1693K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.015); catalogued as COSV59806401; called by muse, mutect2, varscan2
- NCAPH2 | c.862-1G>C p.X288_splice | Splice Site (SNP) | VAF 10/24 reads (42%) | catalogued as COSV52688777; called by muse, mutect2, varscan2
- NCF4 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.365); catalogued as COSV50625284; called by muse, mutect2, varscan2
- NCOA6 | c.5773G>A p.E1925K | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.212); catalogued as rs1202025059, COSV62866057; called by muse, mutect2, varscan2
- NCOA6 | c.2494C>T p.H832Y | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV62866063; called by muse, mutect2, varscan2
- NDUFA1 | c.130C>A p.H44N | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV65097652; called by muse, mutect2, varscan2
- NEB | c.17665C>A p.H5889N | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51440514; called by muse, mutect2, varscan2
- NEB | c.10367G>C p.W3456S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51440549; called by muse, mutect2, varscan2
- NECAB1 | c.115G>C p.D39H | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV70241206, COSV70242363; called by muse, mutect2, varscan2
- NENF | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.426); catalogued as COSV65341366; called by muse, mutect2, varscan2
- NEO1 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.201); catalogued as COSV56075617; called by muse, mutect2, varscan2
- NEURL1 | c.1338C>T p.L446= | Splice Region (SNP) | VAF 16/31 reads (52%) | catalogued as rs1372275527, COSV63915252; called by muse, mutect2, varscan2
- NF1 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV62205875; called by muse, mutect2, varscan2
- NF1 | c.1019C>G p.S340C | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs771089333, CD972347, COSV62200671, COSV62212598; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NIN | c.2602G>C p.E868Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55399725; called by muse, varscan2
- NIPAL1 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55007285; called by muse, mutect2, varscan2
- NIPBL | c.7330G>A p.E2444K | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs1554034440, COSV56959709; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NKPD1 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.916); catalogued as COSV58729629; called by muse, mutect2, varscan2
- NKRF | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV100441771; called by muse, mutect2
- NKTR | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.253); catalogued as COSV51773877; called by muse, mutect2, varscan2
- NLRC5 | c.2633C>A p.S878* | Nonsense Mutation (SNP) | VAF 17/28 reads (61%) | catalogued as COSV52659857; called by muse, mutect2, varscan2
- NLRP12 | c.3096C>G p.L1032= | Splice Region (SNP) | VAF 27/94 reads (29%) | catalogued as COSV60751450, COSV60751504; called by muse, mutect2, varscan2
- NLRP12 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV60743303; called by muse, mutect2, varscan2
- NLRP6 | c.1468G>C p.E490Q | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV56461203; called by muse, mutect2, varscan2
- NLRP8 | c.1235G>A p.R412K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as rs770401932, COSV52591272; called by muse, mutect2, varscan2
- NOC3L | c.1767C>G p.F589L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV64930298; called by muse, mutect2, varscan2
- NOL10 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62041882; called by muse, mutect2
- NOTCH3 | c.6965G>C p.*2322Sext*106 | Nonstop Mutation (SNP) | VAF 23/57 reads (40%) | catalogued as COSV54642613; called by muse, mutect2, varscan2
- NOXRED1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV53628698; called by muse, mutect2, varscan2
- NPAS4 | c.2123C>T p.T708M | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs759012677, COSV60651798; called by muse, mutect2, varscan2
- NPBWR1 | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.24); catalogued as COSV58695851; called by muse, mutect2, varscan2
- NPEPL1 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs764057579, COSV61939360; called by muse, mutect2, varscan2
- NPHP1 | c.902G>C p.R301T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV57210396; called by muse, mutect2, varscan2
- NPHS1 | c.3694C>A p.L1232M | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV62289150; called by muse, mutect2, varscan2
- NPHS1 | c.3376C>G p.Q1126E | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV62289155; called by muse, mutect2, varscan2
- NPY5R | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.158); catalogued as COSV58453084; called by muse, mutect2, varscan2
- NR1D2 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56991167, COSV56993028; called by muse, mutect2, varscan2
- NRXN1 | c.1207G>C p.E403Q | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV58475795; called by muse, mutect2, varscan2
- NSD2 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.65); catalogued as COSV56393904; called by muse, mutect2, varscan2
- NSUN3 | c.504G>C p.L168F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV58936880; called by muse, mutect2, varscan2
- NUDT13 | c.747G>C p.E249D | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1389383972, COSV100624822, COSV61968805; called by muse, mutect2
- NUDT16 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.817); catalogued as COSV63248141, COSV63248711; called by muse, mutect2, varscan2
- NUGGC | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745895030, COSV58437370, COSV58439970; called by muse, mutect2, varscan2
- NUP188 | c.4379C>G p.S1460C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1297646936, COSV65330475, COSV65331529; called by muse, mutect2, varscan2
- NUP214 | c.3187C>T p.Q1063* | Nonsense Mutation (SNP) | VAF 34/82 reads (41%) | catalogued as COSV63911664; called by muse, mutect2, varscan2
- NYNRIN | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.258); catalogued as rs1477235934, COSV66842511, COSV66843885; called by muse, mutect2, varscan2
- OIT3 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.833); catalogued as COSV100468061, COSV61826820; called by muse, mutect2, varscan2
- OLFM3 | c.519C>G p.F173L (on ENST00000338858 / NM_001288821.1; = p.F153L on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (1); PolyPhen possibly damaging (0.899); catalogued as COSV58801571; called by muse, mutect2, varscan2
- OLIG2 | c.254C>G p.S85C | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV60973019; called by muse, mutect2, varscan2
- ONECUT2 | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV72153222; called by muse, mutect2
- OR10A5 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV55055189; called by muse, mutect2, varscan2
- OR1J4 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 47/115 reads (41%) | catalogued as COSV61590122; called by muse, mutect2, varscan2
- OR4D2 | c.547C>G p.Q183E | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV73459822, COSV73459874; called by muse, mutect2, varscan2
- OR52A1 | c.930C>G p.F310L | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV61092900, COSV61093244; called by muse, mutect2, varscan2
- OR5L2 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV101004250, COSV65724490; called by muse, mutect2, varscan2
- OR5M1 | c.200C>A p.S67Y | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs745610743, COSV73202292; called by muse, mutect2, varscan2
- OR6C74 | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs1205676748, COSV59606904; called by muse, mutect2, varscan2
- OR6N1 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58649495; called by muse, mutect2, varscan2
- OR8I2 | c.665C>G p.S222* | Nonsense Mutation (SNP) | VAF 32/91 reads (35%) | catalogued as COSV56169336; called by muse, mutect2, varscan2
- OTOA | c.152C>G p.A51G | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.114); catalogued as COSV53760278; called by muse, mutect2, varscan2
- OTX2 | c.269G>C p.R90T (on ENST00000408990 / NM_172337.3; = p.R98T on NM_021728.4) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100257708, COSV59766930; called by muse, mutect2, varscan2
- P3H1 | c.1979G>C p.G660A | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104376813, COSV52535840; called by muse, mutect2, varscan2
- PA2G4 | c.590G>C p.G197A | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.791); catalogued as COSV57569757; called by muse, mutect2, varscan2
- PA2G4 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV57569764; called by muse, mutect2, varscan2
- PAAF1 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 33/59 reads (56%) | catalogued as COSV60156555, COSV60157060; called by muse, mutect2, varscan2
- PABPN1 | c.833C>G p.S278C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV53729102, COSV53730020; called by muse, mutect2, varscan2
- PAF1 | c.261C>G p.I87M | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55395421; called by muse, mutect2, varscan2
- PAFAH1B2 | c.637A>T p.I213F | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV59167283; called by muse, varscan2
- PAK5 | c.1516G>T p.V506L | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV62033465; called by muse, mutect2, varscan2
- PALB2 | c.2407G>A p.D803N | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV55168004; called by muse, mutect2, varscan2
- PAPOLG | c.1456C>G p.H486D | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV53184347; called by muse, mutect2, varscan2
- PARP10 | c.3032C>T p.S1011F | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.316); catalogued as rs1554746474, COSV57299253; called by muse, mutect2, varscan2
- PBLD | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV53266821; called by muse, mutect2, varscan2
- PCCA | c.1349C>T p.S450L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100886990; called by muse, mutect2, varscan2
- PCDH11X | c.1955C>T p.S652L | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV53446807, COSV53470711; called by muse, mutect2, varscan2
- PCDHB3 | c.491G>C p.R164T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as COSV50601653; called by muse, mutect2, varscan2
- PCDHGA5 | c.2404G>C p.E802Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.025); catalogued as COSV53995737; called by muse, mutect2, varscan2
- PCDHGB1 | c.2008G>C p.D670H | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV53905627, COSV53995723; called by muse, mutect2, varscan2
- PCLO | c.9275C>T p.S3092L | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61652803; called by muse, mutect2, varscan2
- PCNX1 | c.4042G>C p.E1348Q | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53098566; called by muse, mutect2, varscan2
- PCNX4 | c.2356G>A p.E786K (on ENST00000406854 / NM_001330177.2; = p.E552K on NM_022495.5) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV58306301; called by muse, mutect2, varscan2
- PCSK5 | c.3375G>T p.M1125I | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV70451332; called by muse, mutect2, varscan2
- PCSK5 | c.4447G>A p.E1483K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs1478583306, COSV70451334; called by muse, mutect2, varscan2
- PCSK5 | c.5017G>C p.E1673Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.798); catalogued as COSV70451338; called by muse, mutect2, varscan2
- PDE10A | c.2063C>T p.T688M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs1397373586, COSV63097629; called by muse, mutect2, varscan2
- PDE4DIP | c.1891C>A p.L631I | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57715420; called by muse, mutect2, varscan2
- PDHA1 | c.593C>A p.A198D | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV63328857; called by muse, mutect2, varscan2
- PDIA3 | c.46C>G p.L16V | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT tolerated (0.33); PolyPhen benign (0.209); catalogued as rs1243955723, COSV55857471; called by muse, mutect2, varscan2
- PDK1 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs775981849, COSV56374364; called by muse, mutect2, varscan2
- PDS5B | c.1268C>T p.S423L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.046); catalogued as COSV59731161; called by muse, mutect2, varscan2
- PDZD2 | c.6152G>C p.R2051T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV56866627; called by muse, mutect2, varscan2
- PDZD4 | c.1314G>C p.E438D | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.396); catalogued as COSV51248984; called by muse, mutect2, varscan2
- PDZD7 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64647063; called by muse, mutect2, varscan2
- PFKM | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100402593; called by muse, mutect2, varscan2
- PGAP1 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV61323729; called by muse, mutect2, varscan2
- PHB | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.314); catalogued as COSV55931520; called by muse, mutect2, varscan2
- PIK3CA | c.223C>G p.Q75E | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV55924765; called by muse, mutect2, varscan2
- PITPNB | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); catalogued as COSV58062248; called by muse, mutect2, varscan2
- PITPNC1 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100084111, COSV55455070; called by muse, mutect2, varscan2
- PITPNM1 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62709124; called by muse, mutect2, varscan2
- PKD1L2 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV61411157; called by muse, mutect2, varscan2
- PKHD1L1 | c.8927G>A p.R2976K | Missense Mutation (SNP) | VAF 51/85 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs868794887, COSV101006576; called by muse, mutect2, varscan2
- PKP3 | c.1370C>T p.S457L | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs779832282, COSV58988947; called by muse, mutect2, varscan2
- PLA2G12B | c.95C>G p.S32* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | catalogued as COSV65978815; called by muse, mutect2, varscan2
- PLEKHG4B | c.3705C>G p.I1235M (on ENST00000283426; = p.I1591M on NM_052909.5) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV52051836, COSV52058258; called by muse, mutect2
- PLEKHM1 | c.2835G>A p.K945= | Splice Region (SNP) | VAF 4/28 reads (14%) | catalogued as COSV101378801; called by muse, mutect2
- PLEKHM1 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV69599181; called by muse, mutect2, varscan2
- PLEKHM2 | c.3034C>T p.R1012* | Nonsense Mutation (SNP) | VAF 34/71 reads (48%) | catalogued as rs373431155; called by muse, mutect2, varscan2
- PLK4 | c.357G>C p.Q119H | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54638588; called by muse, mutect2, varscan2
- PLXNC1 | c.844G>C p.D282H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.289); catalogued as COSV51579935; called by muse, mutect2
- POF1B | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs769700681, COSV53134884; called by muse, mutect2, varscan2
- POLA1 | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV66889079; called by muse, mutect2, varscan2
- POLB | c.846G>A p.M282I | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.713); catalogued as COSV55183168; called by muse, mutect2, varscan2
- POLG2 | c.1395G>C p.M465I | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.087); catalogued as COSV73376965; called by muse, varscan2
- POLR2A | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV100495925, COSV59494363; called by muse, mutect2, varscan2
- POLRMT | c.1832C>A p.S611Y | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV73933405; called by muse, mutect2, varscan2
- POMGNT2 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.091); catalogued as COSV60954225; called by muse, mutect2, varscan2
- POTEM | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 37/323 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as rs1426720540; called by muse, mutect2, varscan2
- PPIAL4A | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 74/93 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as rs1311931626; called by muse, mutect2, varscan2
- PPP1R16A | c.1330C>G p.P444A | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV52954160, COSV99477291; called by muse, mutect2, varscan2
- PPP1R3A | c.2699C>T p.S900F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV52888355; called by muse, mutect2, varscan2
- PPP1R9B | c.1439C>G p.S480C | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57540634; called by muse, mutect2, varscan2
- PPP4R1 | c.2596C>G p.L866V (on ENST00000400556 / NM_001042388.3; = p.L849V on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as rs1296526196, COSV53283415, COSV99553764; called by muse, mutect2, varscan2
- PPP4R1 | c.1791G>C p.L597F (on ENST00000400556 / NM_001042388.3; = p.L580F on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV53281189; called by muse, mutect2, varscan2
- PPP4R4 | c.1693G>C p.E565Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1237615413, COSV58556725; called by muse, mutect2, varscan2
- PRAMEF4 | c.202C>G p.L68V | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as rs896275228, COSV52440354; called by muse, mutect2, varscan2
- PRDM16 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV54600947; called by muse, mutect2
- PRDM4 | c.124C>G p.H42D | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as COSV57306849, COSV99946401; called by muse, mutect2, varscan2
- PRDM9 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as rs375716818; called by muse, mutect2, varscan2
- PRDX1 | c.552C>G p.I184M | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.345); catalogued as rs765714807, COSV53114205; called by muse, mutect2, varscan2
- PREX1 | c.3793G>A p.E1265K | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV64248911; called by muse, mutect2, varscan2
- PRICKLE3 | c.679G>C p.D227H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66235236; called by muse, mutect2, varscan2
- PRIM1 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as rs770222019, COSV57717854; called by muse, mutect2, varscan2
- PROX1 | c.398C>G p.S133* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV54776793, COSV54781591; called by muse, mutect2, varscan2
- PRPH2 | c.583C>G p.R195G | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as CM125395, CM149323, COSV57836361, COSV57838065; called by muse, mutect2, varscan2
- PRR19 | c.678G>C p.E226D | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV56626748; called by muse, varscan2
- PRRC2C | c.3171G>C p.K1057N (on ENST00000367742; = p.K1055N on NM_015172.4) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV58909647; called by muse, mutect2, varscan2
- PRRT2 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as rs758246761, COSV54885310; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSMD5 | c.76C>T p.H26Y | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV52961439; called by muse, mutect2, varscan2
- PSMD9 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.56); catalogued as COSV55840281; called by muse, mutect2, varscan2
- PSPC1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV100142556, COSV58889638; called by muse, mutect2, varscan2
- PTBP1 | c.1578C>G p.F526L (on ENST00000349038 / NM_031991.4; = p.F552L on NM_002819.5) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62461149; called by muse, mutect2, varscan2
- PTH1R | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.1); catalogued as rs1447631421, COSV57314585, COSV57316930; called by muse, mutect2, varscan2
- PTPA | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 43/108 reads (40%) | catalogued as COSV61235792; called by muse, mutect2, varscan2
- PTPN12 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.184); catalogued as COSV50366506; called by muse, mutect2, varscan2
- PTPRM | c.3049G>C p.E1017Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as rs906394213, COSV59859196, COSV59872040; called by muse, mutect2, varscan2
- PTPRM | c.3607G>C p.E1203Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59872050; called by muse, mutect2, varscan2
- PWWP3A | c.1275C>A p.F425L (on ENST00000627377; = p.F424L on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV60903952; called by muse, mutect2, varscan2
- PXDNL | c.1880C>G p.S627C | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV62494136; called by muse, mutect2, varscan2
- PYY | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV63971338; called by muse, mutect2, varscan2
- R3HCC1L | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV54403722; called by muse, mutect2, varscan2
- RAB20 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57441414; called by muse, mutect2, varscan2
- RAB28 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.091); catalogued as COSV56541333; called by muse, mutect2, varscan2
- RAB7A | c.99C>G p.F33L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54043224; called by muse, mutect2, varscan2
- RADX | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV65319584; called by muse, mutect2, varscan2
- RALBP1 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.026); catalogued as rs1319464221, COSV50037274; called by muse, mutect2, varscan2
- RANBP3L | c.449C>G p.S150C | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV56956915; called by muse, mutect2, varscan2
- RANBP6 | c.3238G>A p.E1080K | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as rs781413061, COSV52390708; called by muse, mutect2, varscan2
- RAP1B | c.116C>G p.S39C | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51669807; called by muse, mutect2, varscan2
- RAPGEF6 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.114); catalogued as rs916450804, COSV57251616; called by muse, mutect2, varscan2
- RASGRP1 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV60366603; called by muse, mutect2, varscan2
- RASSF2 | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1003248601, COSV65082780; called by muse, mutect2, varscan2
- RC3H2 | c.3160G>C p.D1054H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61801776; called by muse, mutect2
- RC3H2 | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV59013974; called by muse, mutect2, varscan2
- RDX | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58195540; called by muse, mutect2, varscan2
- RECK | c.287C>G p.S96C | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV65035939; called by muse, mutect2, varscan2
- REG1A | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.304); catalogued as COSV52070688; called by muse, mutect2, varscan2
- RERE | c.4016C>T p.P1339L | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.958); catalogued as COSV61946784; called by muse, mutect2, varscan2
- RFX5 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV51840502; called by muse, mutect2, varscan2
- RHOBTB3 | c.1784C>T p.A595V | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as rs148767115; called by muse, mutect2, varscan2
- RIOK2 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.74); catalogued as COSV51614114; called by muse, mutect2, varscan2
- RIPOR2 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as COSV52426260; called by muse, mutect2, varscan2
- RLN2 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.816); catalogued as rs372954927; called by muse, mutect2, varscan2
- RMND1 | c.242C>A p.S81Y | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100323749; called by muse, mutect2, varscan2
- RMND5B | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV57745605; called by muse, mutect2, varscan2
- RNASE1 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); catalogued as COSV61754140; called by muse, mutect2, varscan2
- RNF111 | c.2984G>C p.*995Sext*57 (on ENST00000557998 / NM_001270530.1; = p.*987Sext*57 on NM_017610.8 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 38/90 reads (42%) | catalogued as COSV62088426; called by muse, mutect2, varscan2
- RNF112 | c.1304C>G p.S435* | Nonsense Mutation (SNP) | VAF 26/39 reads (67%) | catalogued as COSV71327013, COSV71327094; called by muse, mutect2, varscan2
- RNF14 | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.122); catalogued as COSV61662654; called by muse, mutect2, varscan2
- RNF40 | c.1682G>C p.R561T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.07); catalogued as COSV61215893; called by muse, mutect2, varscan2
- RNF41 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV61504783; called by muse, mutect2, varscan2
- ROCK2 | c.1456G>C p.E486Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.219); catalogued as COSV55082427; called by muse, mutect2, varscan2
- ROPN1B | c.594C>G p.I198M | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52542943; called by muse, mutect2, varscan2
- RPA1 | c.1660-1G>A p.X554_splice | Splice Site (SNP) | VAF 35/52 reads (67%) | catalogued as COSV54611373; called by muse, mutect2, varscan2
- RPAP2 | c.902C>A p.S301* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV72509491; called by muse, mutect2, varscan2
- RPGRIP1 | c.678C>G p.I226M | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as COSV52853939; called by muse, mutect2, varscan2
- RPGRIP1 | c.1563G>C p.K521N | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52853958; called by muse, mutect2, varscan2
- RPL35 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as rs771742167, COSV62019303; called by muse, mutect2, varscan2
- RPL4 | c.966G>C p.L322F | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.46); PolyPhen benign (0.02); catalogued as COSV57181810; called by muse, mutect2, varscan2
- RPL7A | c.30G>C p.K10N | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV59299205; called by muse, mutect2, varscan2
- RRAD | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV55338458, COSV55340404; called by muse, mutect2, varscan2
- RRP1B | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as COSV61479767; called by muse, mutect2, varscan2
705 further variants in this file (326 protein-altering or splice-affecting, 345 silent, 34 other) are not listed here.
